Gene-level copy-number profile of tumor specimen TCGA-55-A48Z-01A from TCGA case TCGA-55-A48Z, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 60.4 years (22,056 days).
Specimen TCGA-55-A48Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.901a7bea-bdc8-4999-928d-f8f77ece5348.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-A48Z-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ec64afa8-2c19-48f1-b8b9-29d7257b15d6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,477; copy number 2: 28,699; copy number 3: 19,586; copy number 4: 2,346; copy number 5: 2,827; copy number 6: 468; copy number 7: 192; copy number 8: 6; copy number 9: 109; copy number 10: 108.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-A48Z-01A-12D-A24O-01): tumor purity 0.41, ploidy 3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,662 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:174,820,027–181,342,213, 235 genes, copy number 5 (broad region; genes not listed).
- chr7:19,813,685–34,299,012, 286 genes, copy number 5 (broad region; genes not listed).
- chr7:41,960,949–62,275,678, 348 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr7:72,558,744–81,335,183, 214 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr8:89,757,806–145,066,685, 893 genes, copy number 5–6 (broad region; genes not listed).
- chr14:45,891,087–46,651,781, 2 genes, copy number 5 (within-gene range 3–5): LINC00871, RPL10L.
- chr14:46,960,423–46,960,546, 1 gene, copy number 5: AL359951.1.
- chr14:50,857,891–59,576,812, 174 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr17:19,020,656–19,756,207, 60 genes, copy number 5: GRAP, AC003957.1, SNORD3B-1, SNORD3B-2, AC007952.3, KYNUP2, AC007952.7, AC007952.2, AC007952.4, SNORD3D, SNORD3D, GRAPL, AC007952.6, AC007952.9, AC007952.1, AC007952.5, AC007952.8, KYNUP1, SNORD3A, SNORD3C, AC106017.1, KYNUP3, EPN2, AC106017.2, EPN2-AS1, B9D1, MIR1180, AC124066.1, MAPK7, MFAP4, AC004448.5, RNF112, AC004448.3, AC004448.2, LINC02094, AC004448.4, RPS2P46, AC004448.1, SLC47A1, RPL17P43, SNORA59B, AC025627.1, SLC47A1P1, AC025627.2, AC025627.3, AC025627.4, MTND1P14, NMTRQ-TTG12-1, MTND2P12, MTCO1P39, SLC47A1P2, ALDH3A2, AC115989.1, Y_RNA, AC005722.2, SLC47A2, AC005722.3, AC005722.4, ALDH3A1, AC005722.1.
- chr19:27,638,483–36,772,825, 300 genes, copy number 7–10 (within-gene range 2–10) (broad region; genes not listed).
- chr19:37,093,019–37,210,512, 1 gene, copy number 9 (within-gene range 2–9): AC012309.1.
- chr19:37,181,579–39,032,785, 86 genes, copy number 9 (broad region; genes not listed).
- chr19:39,834,458–41,074,107, 62 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,477. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
